Somatic mutation profile of tumor specimen TCGA-FY-A3R7-01A (aliquot TCGA-FY-A3R7-01A-11D-A21Z-08) from TCGA case TCGA-FY-A3R7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 50.4 years (18,403 days).
Specimen TCGA-FY-A3R7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b43e6ae-4340-42b6-8cad-5c95f670541e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3R7-10A (Blood Derived Normal), aliquot TCGA-FY-A3R7-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d92a8e9-8fa9-4270-820a-9d4de22ba92f

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KIAA0513 | c.198G>C p.W66C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50740695, COSV50742974; called by muse, mutect2
- MAMLD1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.084); catalogued as rs372258309, COSV53379044; called by muse, mutect2, varscan2
- MDGA2 | c.1936C>G p.R646G (on ENST00000399232 / NM_001113498.2; = p.R348G on NM_182830.4) | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV62082584, COSV62107224, COSV99050703; called by muse, mutect2
- SLC2A14 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as COSV61587954; called by muse, mutect2
- THSD7B | c.4273C>T p.R1425C (on ENST00000272643; = p.R1423C on NM_001316349.2) | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55720044; called by muse, mutect2
